CGCI case HTMCP-02-03-01003 — HIV+ Tumor Molecular Characterization Project - Lung Cancer (CGCI-HTMCP-LC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6611a985-f1c6-4e46-8e69-73cdd92fdad7

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 50 years; Vital status: Dead; Days to death: 1,085 days (3.0 years); Cause of death: Not Cancer Related.

Diagnoses (2)
1. Basaloid squamous cell carcinoma (the primary disease): ICD-O-3 morphology code: 8083/3; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 50.9 years (18,584 days); Year of diagnosis: 2007; Method of diagnosis: Surgical Resection; AJCC staging edition: 6th; AJCC clinical T: T1; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IA; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Prior malignancy: yes; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,001 days (2.7 years).
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 2.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Squamous cell carcinoma, NOS: Tissue or organ of origin: Anus, NOS; Classification of tumor: Prior primary.

Follow-up (3 entries)
- Days to follow up: 0 days; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,001 days (2.7 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day -4,064.

Other clinical attributes
- Day -4,064: Comorbidities: HIV/AIDS.
- Day -4,064: Risk factors: HIV/AIDS.
- Day 0: Weight: 77 kg; CD4 count: 232; Haart treatment indicator: Yes; HIV viral load: 394.
- Day 0: Comorbidities: Hepatitis C Infection.
- Day 0: AIDS risk factors: Pneumonia, NOS.
- Day 0: Risk factors: Hepatitis C Infection.
- Day 0: Cdc hiv risk factors: Intravenous Drug User.

Exposures
- Tobacco smoking status: Current Smoker; Pack years smoked: 18.

Biospecimens (2 samples)
- Sample HTMCP-02-03-01003-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-02-03-01003-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Basaloid Squamous Cell; Tumor status: Tumor free; Tobacco smoking age started: 15; Cause of death: Non-Cancer Related; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; Tobacco smoking history indicator: 2; New tumor event diagnosis indicator: No.
- Anatomic neoplasm subdivision list: Anatomic organ subdivision: Upper lobe.
- History of disease: HIV status: Positive; Year of HIV diagnosis: 1996; Hcv test results: Positive; Haart therapy at diagnosis: No; Haart therapy prior to diagnosis: Yes; Prior aids conditions: Pneumonia, recurrent; Cdc HIV risk group: IV drug user; History relevant infectious diagnosis: Hepatitis C.
- Primary pathology: Lymph nodes examined: Yes.
